Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6B8, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6B8-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

CC:
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Right upper back biopsy proven pleomorphic sarcoma.

Specimens Submitted:
1: SP: High grade sarcoma, posterior rt. scapula

DIAGNOSIS:

- 1) SOFT TISSUE MASS, SCAPULA, RIGHT POSTERIOR; RESECTION:
- PLEOMORPHIC SARCOMA, HIGH GRADE. IMMUNOHISTOCHEMICALLY, THE TUMOR CELLS ARE POSITIVE FOR DESMIN AND COMMON MUSCLE ACTIN (HHF-35), AND NEGATIVE FOR S-100 PROTEIN AND CD34. THE STAINING PATTERN INDICATES SMOOTH MUSCLE DIFFERENTIATION AND IS CONSISTENT WITH LEIOMYOSARCOMA.
- THE TUMOR SIZE IS 17.2 CM. APPROXIMATELY 30% OF THE TUMOR IS NECROTIC.
- THE TUMOR IS FOCALLY COATED BY A FIBROUS CAPSULE. HOWEVER, FOCALLY, THE TUMOR HAS AN INFILTRATIVE BORDER, WITH INFILTRATION INTO SURROUNDING SOFT TISSUE AND SKELETAL MUSCLE.
- THE MARGINS APPEAR FREE BUT FOCALLY CLOSE (WITHIN 1.0 MM OF THE INKED SURFACE FOCALLY).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
POSITIVE	SMA	
POSITIVE	CMA (HHF35)	
POSITIVE	DES CONT	
NEGATIVE	S-100	
NEGATIVE	CD34	
EQUIV	EMA	
EQUIV	SMA	
POSITIVE	CMA (HHF35)	

PATH
REPORT

** Continued on next page **

ICD-O-3

Leiomyosarcoma NOS 8850/3

Site: C6CF Connective, subcutaneous and other soft tissues of extremities C49.9

path Connective, subcutaneous and other soft tissues of scapular region C49.3

pd 5/21/13

[page 2 of 2]
SURGICAL

Page 2 of 2

POSITIVE DES CONT
NEGATIVE S-100
NEGATIVE CD34
EQUIV EMA
NEG CONT
IMM RECUT
NEG CONT
IMM RECUT

Gross Description:

1) The specimen is received fresh, labeled "High grade sarcoma, posterior right scapula". It consists of a 20.8 x 14.3 x 13.4 cm unoriented segment of adipose tissue, fascia, and skeletal muscle. A 17.2 x 11.2 x 10.3 cm mass is present and is involving the skeletal muscle. The mass is composed of the fleshy, tan-white, gray, soft tissue and has a 6.2 x 6.0 x 4.0 cm area with hemorrhage and necrosis. The deep margin, and superficial margin are recognized. The mass is within less than 0.1 cm of the deep surgical margin and 3.0 cm of the superficial margin. In reference to the undesignated peripheral margins, the mass is 1.0 cm from the closest peripheral margin, and is 1.6 cm, 2.0 cm and 2.1 cm from the other peripheral margins. A photograph of the specimen is taken. A section is submitted for TPS and EM studies. Representative sections are submitted.

Summary of Sections:

DE mass with deep margin
PE peripheral margins (block six, the closest peripheral margin)
MA mass (blocks 11 through 16 area with a fleshy white-tan appearance, blocks 17 through 19 area with hemorrhagic and necrotic appearance)

Summary of Sections:

Part 1: SP: High grade sarcoma, posterior rt. scapula

Block	Sect.	Site	PCs
5	DE		5
9	MA		9
5	PE		5

PATH
REPORT

** End of Report **

Source: NCI Genomic Data Commons file b9f22a67-b2cd-4103-9fb9-894759e29197 (TCGA-DX-A6B8.A4F705B7-0BC7-47B9-85F6-7C81A9D1D3C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).